Somatic mutation profile of tumor specimen TCGA-HT-A74L-01A (aliquot TCGA-HT-A74L-01A-11D-A32B-08) from TCGA case TCGA-HT-A74L, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 22.6 years (8,240 days).
Specimen TCGA-HT-A74L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4abea1b3-1506-4b10-b352-b6a6ca5847d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A74L-10A (Blood Derived Normal), aliquot TCGA-HT-A74L-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22f5ef29-9cae-408e-aae5-a1f33aabfe6e

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- APCDD1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV100789977, COSV100790017; called by muse, mutect2, varscan2
- COX20 | c.157+1G>C p.X53_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100834680; called by muse, mutect2, varscan2
- ELOVL6 | c.622A>C p.M208L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100165240; called by muse, mutect2, varscan2
- KIAA1522 | c.500C>T p.P167L (on ENST00000373480 / NM_001198972.2; = p.P226L on NM_020888.3) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs201274811; called by muse, mutect2, varscan2
- LY9 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99626203; called by muse, mutect2
- MACF1 | c.20872C>T p.R6958C (on ENST00000372915; = p.R5003C on NM_012090.5) | Missense Mutation (SNP) | VAF 17/19 reads (89%) | catalogued as rs1217328487, COSV99245071; called by muse, mutect2, varscan2
- MUC16 | c.1936G>A p.G646S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs757867454, COSV67495248; called by muse, mutect2, varscan2
- NPR2 | c.1352-2A>G p.X451_splice | Splice Site (SNP) | VAF 49/119 reads (41%) | catalogued as COSV100709504; called by muse, mutect2, varscan2
- OR5R1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1179349890, COSV100393479; called by muse, mutect2, varscan2
- SLC22A13 | c.1211G>T p.C404F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100314583; called by muse, mutect2, varscan2
- USP14 | c.654A>G p.I218M | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.285); catalogued as COSV99864180; called by muse, mutect2
- YWHAB | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV100803178; called by muse, mutect2, varscan2
- MYO3B | c.2178C>T p.F726= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs1168381839, COSV58709971; called by muse, mutect2, varscan2
- PRKG1 | c.942T>C p.D314= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100907302; called by muse, mutect2, varscan2
- SMC4 | c.3138T>A p.P1046= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100557515; called by muse, mutect2, varscan2
- VWA2 | c.2058C>T p.I686= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100073759; called by muse, mutect2, varscan2
